Somatic mutation profile of tumor specimen TCGA-GU-A42Q-01A (aliquot TCGA-GU-A42Q-01A-11D-A23U-08) from TCGA case TCGA-GU-A42Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,534 days).
Specimen TCGA-GU-A42Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a6ddc84-6fef-45e9-aff9-da0676f69d65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-A42Q-10A (Blood Derived Normal), aliquot TCGA-GU-A42Q-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09f10f0f-f7b6-4af0-b758-766a86411a4b

The open-access MAF lists 201 somatic variants for this specimen: 145 protein-altering or splice-affecting, 53 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 53, Nonsense Mutation 15, In Frame Ins 2, RNA 2, Splice Site 2, Intron 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB10 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60620606, COSV60623614; called by muse, mutect2, varscan2
- AC008397.2 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); catalogued as COSV53206284, COSV99441114, COSV99442346; called by muse, mutect2, varscan2
- ACBD5 | c.619G>A p.E207K (on ENST00000375888 / NM_001352568.1; = p.E198K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV65518690; called by muse, mutect2
- ALAS1 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs749651370, COSV59627500; called by muse, mutect2, varscan2
- ANGPTL4 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1412783203, COSV56845369; called by muse, mutect2, varscan2
- ANO5 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1200514344; called by muse, mutect2, varscan2
- ARHGAP29 | c.2356G>T p.D786Y | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV53110405; called by muse, mutect2, varscan2
- ARHGEF25 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV54085722; called by muse, mutect2, varscan2
- BEST3 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV58300502; called by muse, mutect2, varscan2
- BFAR | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as rs574985188, COSV55492990; called by muse, mutect2, varscan2
- BPIFC | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV55911799; called by muse, mutect2, varscan2
- C3orf70 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV58587210; called by muse, mutect2, varscan2
- CAND1 | c.2102T>C p.I701T | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV73389577; called by muse, mutect2, varscan2
- CASP8 | c.780G>C p.R260S (on ENST00000432109 / NM_033355.3; = p.R277S on NM_001228.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99965876; called by muse, mutect2
- CD83 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.578); catalogued as rs753290670, COSV64787803; called by muse, mutect2, varscan2
- CELSR2 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54769452; called by muse, mutect2, varscan2
- CEP78 | c.2008G>C p.E670Q (on ENST00000424347 / NM_001349840.2; = p.E671Q on NM_032171.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.307); catalogued as COSV52846574; called by muse, mutect2, varscan2
- CEP89 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99993952; called by muse, varscan2
- CEP97 | c.2569C>T p.Q857* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as COSV100512062; called by muse, mutect2, varscan2
- CHAF1A | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775109223, COSV56671455; called by muse, mutect2, varscan2
- CHD2 | c.5138G>C p.R1713T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.966); catalogued as COSV67708074; called by muse, mutect2, varscan2
- CHMP4B | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV54135601; called by muse, mutect2, varscan2
- DDX23 | c.1669A>G p.M557V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV56397779; called by muse, mutect2, varscan2
- DGKK | c.2053G>C p.D685H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV65707029; called by muse, mutect2, varscan2
- DNMBP | c.2038C>G p.H680D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.015); catalogued as COSV60623616; called by muse, mutect2, varscan2
- DOCK8 | c.4237G>T p.D1413Y | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV66619185; called by muse, mutect2, varscan2
- DOCK8 | c.5922G>C p.Q1974H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66619192; called by muse, mutect2, varscan2
- DYNC1LI1 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV56127245; called by muse, mutect2
- EAF2 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs766289522, COSV56544018; called by muse, mutect2, varscan2
- EHMT2 | c.2176G>T p.V726L | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.29); catalogued as COSV100977193, COSV64995397; called by muse, mutect2, varscan2
- ELOVL1 | c.587G>A p.W196* | Nonsense Mutation (SNP) | VAF 21/155 reads (14%) | catalogued as COSV100196634; called by muse, mutect2, varscan2
- EPB42 | c.881C>T p.S294L (on ENST00000441366 / NM_001114134.2; = p.S324L on NM_000119.3) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.93); catalogued as COSV55749258; called by muse, mutect2, varscan2
- ESF1 | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52520213; called by muse, mutect2, varscan2
- FAM50A | c.112-2A>T p.X38_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99341195; called by muse, mutect2, varscan2
- FBXO39 | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 69/114 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV58621489; called by muse, mutect2, varscan2
- FBXW7 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99905601; called by muse, mutect2, varscan2
- FSCB | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 61/159 reads (38%) | catalogued as COSV100469797; called by muse, mutect2, varscan2
- GABPB2 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV64460695; called by muse, mutect2, varscan2
- GALNT13 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV67216416; called by muse, mutect2, varscan2
- GALNT17 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV61156434; called by muse, mutect2, varscan2
- GALNT3 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV67061617; called by muse, mutect2, varscan2
- GEMIN5 | c.2526G>T p.K842N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV53559761; called by muse, mutect2, varscan2
- GLI3 | c.4444C>T p.P1482S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV67887230; called by muse, mutect2, varscan2
- GOLGA2 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs775544000, COSV70168228; called by muse, mutect2, varscan2
- GOLGB1 | c.4475G>A p.R1492Q | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779641750, COSV61464133, COSV61471372; called by muse, mutect2, varscan2
- GRHL2 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1394251742, COSV52546988; called by muse, mutect2, varscan2
- GUCY1A1 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); catalogued as COSV56650796; called by muse, mutect2, varscan2
- GUK1 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as COSV57154709; called by muse, mutect2, varscan2
- HAS2 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58263162; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.600G>C p.R200S (on ENST00000354667 / NM_031243.3; = p.R188S on NM_002137.4) | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as COSV61158576; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.46G>C p.E16Q (on ENST00000354667 / NM_031243.3; = p.E4Q on NM_002137.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61158586, COSV61158722; called by muse, mutect2, varscan2
- HNRNPL | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.084); catalogued as rs1040971385, COSV55492005; called by muse, mutect2, varscan2
- HSPA9 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV51864113; called by muse, mutect2, varscan2
- HTR4 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.397); catalogued as COSV58792939; called by muse, mutect2, varscan2
- IGSF10 | c.4796G>A p.G1599D | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs374980131; called by muse, mutect2, varscan2
- IMPA2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52319274; called by muse, mutect2, varscan2
- KANSL1 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV52267144, COSV52272385; called by muse, mutect2, varscan2
- KEAP1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50263607, COSV50635893; called by muse, mutect2, varscan2
- KIAA0319 | c.1960G>A p.G654S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1454966517, COSV65497561; called by muse, mutect2, varscan2
- KIDINS220 | c.4442A>C p.E1481A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56752140; called by muse, mutect2, varscan2
- KIRREL2 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.595); catalogued as COSV52875532; called by muse, mutect2, varscan2
- KLHDC2 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV53586497; called by muse, mutect2, varscan2
- KLHL21 | c.1036T>A p.S346T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.07); catalogued as rs369651794; called by muse, mutect2, varscan2
- LRTM2 | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1365262978, COSV54564553; called by muse, mutect2, varscan2
- LUC7L2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54925184; called by muse, mutect2, varscan2
- LY6H | c.186C>T p.S62= | Splice Region (SNP) | VAF 28/94 reads (30%) | catalogued as COSV61370600; called by muse, mutect2, varscan2
- MACF1 | c.19885G>C p.D6629H (on ENST00000372915; = p.D4674H on NM_012090.5) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV57109016; called by muse, varscan2
- MATK | c.727G>C p.E243Q (on ENST00000310132 / NM_139355.3; = p.E244Q on NM_002378.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.321); catalogued as COSV59554057; called by muse, mutect2, varscan2
- MCM2 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as COSV99413004, COSV99413437; called by muse, mutect2, varscan2
- MED26 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1345608147, COSV54659719; called by muse, mutect2, varscan2
- MEIOC | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV63439753; called by muse, mutect2, varscan2
- MEPCE | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV52769000; called by muse, mutect2, varscan2
- MET | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59259606; called by muse, mutect2, varscan2
- MUC5B | c.5987C>T p.S1996L | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV71591257; called by muse, mutect2, varscan2
- MYH6 | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as rs759408374, COSV62447730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYPN | c.3019G>C p.E1007Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.692); catalogued as COSV100590563; called by muse, mutect2
- NAALADL2 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.172); catalogued as COSV101495478; called by muse, mutect2
- NCKAP5 | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58437689, COSV58437876; called by muse, mutect2, varscan2
- NDST4 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99996969; called by muse, mutect2, varscan2
- NPC1L1 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV56923221, COSV56926471; called by muse, mutect2, varscan2
- NRXN1 | c.3478C>T p.Q1160* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100456739, COSV58490326; called by muse, mutect2, varscan2
- NUP205 | c.4946T>G p.L1649R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53657481; called by muse, mutect2, varscan2
- OR52B6 | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV61447671; called by muse, mutect2, varscan2
- PARD3 | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs115076370, COSV60747870; called by muse, mutect2, varscan2
- PCDHGA11 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.074); catalogued as COSV53927658; called by muse, mutect2, varscan2
- PCYOX1L | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV51002347; called by muse, mutect2, varscan2
- PER3 | c.713A>T p.H238L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV62705288; called by muse, mutect2, varscan2
- PFN3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as COSV99499465; called by muse, mutect2
- PHC2 | c.2096G>A p.R699Q (on ENST00000257118 / NM_198040.2; = p.R164Q on NM_004427.4) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV57103203; called by muse, mutect2
- PHF3 | c.4853C>G p.S1618C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs773783440, COSV50316093; called by muse, mutect2, varscan2
- PIK3R5 | c.2113G>T p.A705S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52652659; called by muse, mutect2, varscan2
- PIP4K2C | c.1200C>G p.I400M | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61605940; called by muse, mutect2, varscan2
- PLCD3 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV59559904, COSV59560716; called by muse, mutect2, varscan2
- PPARGC1B | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58528330; called by muse, mutect2, varscan2
- PPDPFL | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV57460875, COSV57460969; called by muse, mutect2, varscan2
- PPP1R12B | c.2575C>T p.R859C | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs769365526, COSV51783889; called by muse, mutect2, varscan2
- PSMD2 | c.2717A>G p.Y906C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1284457588, COSV59529388; called by muse, mutect2, varscan2
- PTPN13 | c.5861C>A p.S1954* (on ENST00000411767 / NM_080683.3; = p.S1935* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100365390; called by muse, mutect2, varscan2
- PTPRF | c.5299G>C p.D1767H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63444176; called by muse, varscan2
- RAPGEF1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV64698935; called by muse, mutect2, varscan2
- RIPK4 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60186593; called by muse, mutect2, varscan2
- RNASEL | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62376159; called by muse, mutect2, varscan2
- RNF139 | c.1934G>C p.R645T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.879); catalogued as COSV52678815; called by muse, mutect2, varscan2
- RNF168 | c.1572G>C p.K524N | Missense Mutation (SNP) | VAF 156/326 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV58837238; called by muse, mutect2, varscan2
- RPH3A | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV101231886; called by muse, mutect2, varscan2
- RXFP4 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs761985012, COSV58143598; called by muse, mutect2, varscan2
- RYR3 | c.5141T>C p.V1714A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs374176908; called by muse, mutect2, varscan2
- SAG | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68590710; called by muse, varscan2
- SAP30BP | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.079); catalogued as COSV53127426; called by muse, mutect2, varscan2
- SESN1 | c.1122G>C p.L374F (on ENST00000356644 / NM_001199933.1; = p.L433F on NM_014454.3) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as COSV57420564; called by muse, mutect2, varscan2
- SGCE | c.1456C>T p.Q486* (on ENST00000647096; = p.Q423* on NM_003919.3) | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as rs766199553, COSV99722901; called by muse, mutect2, varscan2
- SLC30A6 | c.255G>C p.L85F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV50872272; called by muse, mutect2, varscan2
- SLC4A11 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755108289, COSV66261381; called by muse, mutect2
- SLC4A9 | c.2765G>A p.R922Q (on ENST00000507527 / NM_001258428.2; = p.R898Q on NM_031467.3) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762998447, COSV50195995; called by muse, mutect2, varscan2
- SMCHD1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55254907; called by muse, mutect2, varscan2
- SMOC2 | c.1303G>T p.E435* (on ENST00000356284 / NM_001166412.2; = p.E446* on NM_022138.3) | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100635560; called by muse, mutect2, varscan2
- SNRNP27 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as rs760270782, COSV99732233; called by muse, mutect2, varscan2
- SNTG1 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52423849, COSV52436265; called by muse, mutect2, varscan2
- SPG11 | c.4451C>G p.S1484C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as COSV55993310; called by muse, mutect2, varscan2
- SYT9 | c.1065G>C p.E355D | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV59616422; called by muse, mutect2, varscan2
- TAGAP | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.276); catalogued as COSV57851154, COSV57853125; called by muse, mutect2, varscan2
- TBC1D4 | c.1168C>G p.Q390E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66488590, COSV66490927; called by muse, mutect2, varscan2
- TCF4 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV61893973; called by muse, mutect2, varscan2
- TFRC | c.1273C>G p.L425V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.76); catalogued as rs1348086870, COSV64054410; called by muse, mutect2, varscan2
- TMEM67 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV60037960; called by muse, mutect2, varscan2
- TRIM24 | c.3136C>T p.R1046C (on ENST00000343526 / NM_015905.3; = p.R1012C on NM_003852.4) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs769470209, COSV58971029; called by muse, mutect2, varscan2
- TTC17 | c.1972C>G p.L658V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50007519; called by muse, mutect2, varscan2
- TTC37 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV62454399; called by muse, mutect2, varscan2
- UBASH3A | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52311715; called by muse, mutect2, varscan2
- UNC45A | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs376117199; called by muse, mutect2, varscan2
- YWHAG | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56900593, COSV56900620; called by muse, mutect2, varscan2
- ZFYVE16 | c.2103C>G p.F701L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV62015276; called by muse, mutect2, varscan2
- ZIC4 | c.923C>G p.S308W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67171209; called by muse, mutect2, varscan2
- ZNF181 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.83); PolyPhen benign (0.287); catalogued as COSV67626630; called by muse, mutect2, varscan2
- ZNF219 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV100070671; called by muse, mutect2
- ZNF573 | c.886C>T p.H296Y (on ENST00000536220 / NM_001172692.1; = p.H238Y on NM_152360.3) | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59824670; called by muse, mutect2, varscan2
- ZNF714 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV52510963, COSV99395439; called by muse, mutect2, varscan2
- ZNF821 | c.295G>A p.E99K (on ENST00000425432 / NM_001376297.1; = p.E57K on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs368720139, COSV57987167; called by muse, mutect2, varscan2
- EEF1D | c.733_738del p.I245_Q246del | In Frame Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- IGKV3D-15 | c.146T>G p.V49G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, varscan2
- PITPNM2 | c.2164_2165insCCC p.D721_L722insP | In Frame Ins (INS) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- ZNF106 | c.3029_3031dup p.D1010dup | In Frame Ins (INS) | VAF 23/156 reads (15%) | called by mutect2, pindel, varscan2
- ZNF395 | c.1110dup p.L371Sfs*114 | Frame Shift Ins (INS) | VAF 12/100 reads (12%) | called by mutect2, pindel, varscan2
- AP1M2 | c.993C>T p.S331= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1176313174, COSV99141014; called by muse, mutect2, varscan2
- CHD7 | c.8640G>A p.P2880= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs374937585, COSV71110773; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CNBD2 | c.954G>A p.L318= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV62586725; called by muse, mutect2, varscan2
- CPN1 | c.837C>T p.I279= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV64942145; called by muse, mutect2, varscan2
- CYP1A2 | c.537G>C p.L179= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV59659509; called by muse, mutect2, varscan2
- CYP8B1 | c.204C>T p.F68= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV60226074; called by muse, mutect2, varscan2
- DSG2 | c.1530A>G p.A510= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV55198276; called by muse, mutect2, varscan2
- ERAP2 | c.207C>T p.L69= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV65939342; called by muse, mutect2, varscan2
- ETNK1 | c.831G>A p.Q277= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV56884681; called by muse, mutect2, varscan2
- FGF8 | c.480G>A p.Q160= (on ENST00000344255 / NM_033164.4; = p.Q142= on NM_006119.6) | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV60142688, COSV60143440; called by muse, mutect2, varscan2
- FKBP9 | c.1554C>T p.H518= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs574102091, COSV99640397; called by muse, mutect2, varscan2
- FOXB2 | c.174G>A p.Q58= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV65022801; called by muse, mutect2, varscan2
- HSPG2 | c.5373C>T p.F1791= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV65970617; called by muse, varscan2
- KCNAB2 | c.495G>A p.P165= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs750883348, COSV51236241; called by muse, mutect2, varscan2
- KLB | c.1932G>T p.P644= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV57301106; called by muse, mutect2, varscan2
- KMT5B | c.153G>A p.S51= | Silent (SNP) | VAF 66/175 reads (38%) | catalogued as rs1219176565, COSV58565416; called by muse, mutect2, varscan2
- KPRP | c.1449G>T p.A483= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV64221388, COSV64221642; called by muse, mutect2, varscan2
- KY | c.105G>C p.A35= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV101415033; called by muse, mutect2
- LAMB1 | c.3639C>T p.I1213= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs141885441, COSV55966155; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCMT2 | c.1176C>G p.L392= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs751121071, COSV59790087; called by muse, mutect2, varscan2
- LRP2 | c.13086G>A p.G4362= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV55548753; called by muse, mutect2, varscan2
- MAP3K7 | c.471G>C p.L157= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV65232582; called by muse, mutect2, varscan2
- MRPL17 | c.9G>A p.L3= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs766093779, COSV56618267; called by muse, mutect2, varscan2
- MXRA5 | c.2172C>G p.L724= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV54231274; called by muse, mutect2, varscan2
- NOX5 | c.1077C>T p.G359= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV52987201; called by muse, mutect2, varscan2
- NUDT16L1 | c.531C>G p.L177= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs761186574, COSV52150134; called by muse, mutect2, varscan2
- PIGG | c.1611G>A p.R537= (on ENST00000453061 / NM_001127178.3; = p.R529= on NM_017733.4) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV56317409; called by muse, mutect2, varscan2
- PLPPR2 | c.606C>T p.R202= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs778658442, COSV52259439; called by muse, mutect2, varscan2
- PRICKLE1 | c.120G>C p.L40= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV61542707; called by muse, mutect2, varscan2
- PRRC2A | c.24T>C p.T8= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as COSV63224451; called by muse, mutect2, varscan2
- PTH2 | c.204C>T p.D68= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99569625; called by muse, mutect2, varscan2
- PTPRF | c.5346C>T p.F1782= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV63444182; called by muse, varscan2
- RHO | c.273C>T p.F91= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV56213067; called by muse, mutect2, varscan2
- RTL9 | c.3984C>T p.A1328= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV71825493; called by muse, mutect2, varscan2
- SALL1 | c.1872C>T p.S624= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs143548629; called by muse, mutect2, varscan2
- SLC19A3 | c.1341A>T p.A447= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV51454913, COSV51455447; called by muse, mutect2
- SLC1A5 | c.267C>T p.F89= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1046172272, COSV101314819; called by muse, mutect2, varscan2
- SLC30A8 | c.907C>T p.L303= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV69969627; called by muse, mutect2, varscan2
- SPATA17 | c.438G>A p.E146= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV65120940; called by muse, mutect2, varscan2
- SRRM2 | c.6933C>T p.L2311= | Silent (SNP) | VAF 71/252 reads (28%) | catalogued as COSV51940356; called by muse, mutect2, varscan2
- TCHH | c.5667G>A p.Q1889= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as rs374186199, COSV64276294; called by muse, mutect2, varscan2
- TIAM2 | c.810C>T p.P270= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs140507023; called by muse, mutect2, varscan2
- TUBB6 | c.810C>T p.F270= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs776288663, COSV52313902; called by muse, mutect2, varscan2
- TXNRD2 | c.1476G>A p.R492= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV68691905; called by muse, mutect2, varscan2
- UNC5D | c.1342C>T p.L448= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV54784125; called by muse, mutect2, varscan2
- USP45 | c.2253G>C p.V751= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV59679916; called by muse, mutect2, varscan2
- VPS13D | c.12234G>A p.L4078= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV50631510, COSV50659533; called by muse, mutect2, varscan2
- VPS4B | c.75G>C p.G25= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV53069045; called by muse, mutect2, varscan2
- YPEL1 | c.57A>G p.R19= | Silent (SNP) | VAF 70/283 reads (25%) | catalogued as COSV59756555; called by muse, mutect2, varscan2
- ZNF23 | c.1119C>T p.F373= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV61840752; called by muse, mutect2, varscan2
- ZNF275 | c.543C>T p.F181= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV64704314; called by muse, mutect2, varscan2
- ZNF516 | c.3114C>G p.V1038= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV71586881; called by muse, varscan2
- ZNF626 | c.621C>G p.G207= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV74129274, COSV74129489; called by muse, mutect2, varscan2
- AMACR | c.739+1293A>G | Intron (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100163243; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.493T>C | RNA (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- SNORD116-6 | n.17C>G | RNA (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
